Surgical pathology report (de-identified scan), TCGA case TCGA-NC-A5HI, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CHUV, specimen TCGA-NC-A5HI-01A (Primary Tumor).

ICD-O-3
Carcinoma, Squamous cell NOS
8070/3

Site: (R) Lung, lower lobe
C34.3

Synoptic translated report

JW 2/1/13

Site : Right lung inferior lobe

☐ Central ☒ Peripheral ☐ NA

Number of lesion :

1. Lung squamous cell carcinoma

Tumor size:

1. 7.0 x 4.5 x 4.0 cm

Visceral pleural invasion: ☐ Yes ☒ No ☐ NA

Chest wall invasion : ☐ Yes ☒ No ☐ NA

Histological diagnosis : Moderately differentiated squamous carcinoma

Node status : N0 (0/20)

TNM : pT2 pN0 (0/20) G2 R0

Pathologist signature:

Date:

HPVAA Discrepancy		
Dual/Syncopious Primary Sites		

Source: NCI Genomic Data Commons file 705d43f7-98f3-468b-93b2-712ac440cc91 (TCGA-NC-A5HI.45450CB6-9903-40AD-97D4-18BEF2ED87CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).